Somatic mutation profile of tumor specimen TCGA-EL-A3T2-01A (aliquot TCGA-EL-A3T2-01A-11D-A22D-08) from TCGA case TCGA-EL-A3T2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 55.9 years (20,403 days).
Specimen TCGA-EL-A3T2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d6bd051-a603-4308-a24a-ad25aac6b3de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T2-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T2-11A-11D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e984f8-da88-4842-8211-3772c7f2d3a3

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Splice Site 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 75/175 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.7609-1G>C p.X2537_splice | Splice Site (SNP) | VAF 10/113 reads (9%) | catalogued as COSV59442512; called by muse, mutect2
- FCN2 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52476809; called by muse, mutect2
- FLVCR2 | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53162131; called by muse, mutect2
- KDM2B | c.3797C>A p.T1266N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65640354; called by muse, varscan2
- NIPBL | c.3664+1G>A p.X1222_splice | Splice Site (SNP) | VAF 35/86 reads (41%) | catalogued as COSV56950190; called by muse, mutect2, varscan2
- NSD3 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1376200162, COSV57618371; called by muse, mutect2, varscan2
- STAG2 | c.2729T>G p.I910R | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV54357347; called by muse, mutect2, varscan2
- THBS3 | c.2078A>G p.N693S | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV64249250; called by muse, mutect2, varscan2
- TMX3 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55185196; called by muse, mutect2
- UBR3 | c.3650A>T p.D1217V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as COSV55848588; called by muse, mutect2, varscan2
- MAGI1 | c.2721G>A p.E907= (on ENST00000402939 / NM_001033057.2; = p.E935= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/275 reads (36%) | catalogued as COSV58322784, COSV58324388; called by muse, mutect2, varscan2
